Gene-level copy-number profile of tumor specimen CDDP-ABKE-TTP1-A from CDDP_EAGLE case CDDP-ABKE, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62 years.
Specimen CDDP-ABKE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f9d747d0-db36-475c-8445-f9afb31ee50d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABKE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/64736872-1921-4ac5-afc1-254d4e7cd8a2

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 8; copy number 2: 508; copy number 3: 15,566; copy number 4: 4,610; copy number 5: 11,500; copy number 6: 21,948; copy number 7: 913; copy number 8: 1,069; copy number 9: 2,604; copy number 10: 12; copy number 12: 146.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–3): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–4): AC114786.3.
- chr5:86,353,803–86,368,854, 1 gene: AC016550.2.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–3): AL772307.1.
- chr9:40,105,822–40,106,527, 1 gene: AL773545.3.
- chr9:61,330,717–61,582,675, 3 genes: CNTNAP3C, RN7SL462P, AL935212.3.
- chr9:65,189,995–65,250,826, 4 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
